Gene-level copy-number profile of tumor specimen TCGA-W5-AA36-01A from TCGA case TCGA-W5-AA36, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 51.7 years (18,882 days).
Specimen TCGA-W5-AA36-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.df8d6b25-985f-476f-a4b3-5d3decf0ea61.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W5-AA36-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c80035dd-1b9b-4327-ab40-e27dcafa20bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 8,405; copy number 2: 50,027; copy number 3: 1,342.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W5-AA36-01A-11D-A416-01): tumor purity 0.86, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 8 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr12:752,579–911,452, 3 genes (within-gene range 0–1): WNK1, RNU4ATAC16P, AC004765.1.
- chr14:50,632,058–51,730,727, 31 genes (within-gene range 0–1): SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.3, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2, TRIM9, AL358334.4, AL591770.1, TMX1, SNORA70, Y_RNA, LINC00519, LINC00640, AL358332.1, LINC02310, SETP2, FRMD6-AS2, FRMD6, RNU6-1291P, AL122125.1, FRMD6-AS1, RNA5SP385.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,405. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
